Somatic mutation profile of tumor specimen TCGA-HC-7742-01A (aliquot TCGA-HC-7742-01A-11D-2114-08) from TCGA case TCGA-HC-7742, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.4 years (21,323 days).
Specimen TCGA-HC-7742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 095b74df-ed4e-4bd6-9e51-a3b6774f7d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7742-10A (Blood Derived Normal), aliquot TCGA-HC-7742-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/878d2882-3d6f-4580-8e78-e47fa25ebebf

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTL7B | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263764064, COSV65926824; called by muse, mutect2, varscan2
- APOB | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs1438429086, COSV51943150, COSV51951559; called by muse, mutect2
- ATP8B2 | c.385G>T p.D129Y (on ENST00000672630; = p.D96Y on NM_001005855.2) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59247255; called by muse, mutect2, varscan2
- C6 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 61/205 reads (30%) | catalogued as rs191386155, COSV54713377; called by muse, mutect2, varscan2
- CIART | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs782442348, COSV51745043; called by muse, mutect2, varscan2
- DLGAP3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147968723, COSV52394894; called by muse, mutect2, varscan2
- ELAVL2 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV56365676; called by muse, mutect2, varscan2
- IGDCC3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs759398176, COSV60078613; called by muse, mutect2, varscan2
- IRAK1 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64110005, COSV64112080; called by muse, mutect2, varscan2
- KCNN1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV55840258; called by muse, mutect2, varscan2
- KLK6 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777841287, COSV100037817, COSV59565159; called by muse, mutect2, varscan2
- LAMC2 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51457579; called by muse, mutect2, varscan2
- MECOM | c.2180G>A p.R727Q (on ENST00000468789 / NM_001105078.4; = p.R915Q on NM_004991.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1266973210, COSV52959477; called by muse, mutect2, varscan2
- OR2F2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68833052; called by muse, mutect2, varscan2
- RAG1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs762022709, COSV55024626; called by muse, mutect2, varscan2
- SEC31B | c.3275C>A p.S1092Y | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV64845025; called by muse, mutect2, varscan2
- TBC1D5 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV53763411; called by muse, mutect2, varscan2
- TMEM132B | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751942292, COSV54747583; called by muse, mutect2, varscan2
- TRPM5 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs367824428; called by muse, mutect2, varscan2
- UPP1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201808602, COSV57976975; called by muse, mutect2, varscan2
- USP2 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867511194, COSV52730794; called by muse, mutect2, varscan2
- XCL1 | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63192519; called by muse, mutect2, varscan2
- BRAF | c.1922_1933del p.K641_W644del (on ENST00000288602 / NM_001374244.1; = p.K601_W604del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- ABCA13 | c.9582C>T p.S3194= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs773229518, COSV71291236; called by muse, mutect2, varscan2
- COASY | c.1404G>T p.V468= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV55899524; called by muse, mutect2, varscan2
- MCHR2 | c.516G>A p.S172= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs140465249, COSV56000919; called by muse, mutect2, varscan2
- MRPL54 | c.9C>G p.T3= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as COSV57463191; called by muse, mutect2, varscan2
- RYR2 | c.14493C>T p.I4831= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs375456172; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSC22D1 | c.1515A>G p.Q505= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as rs774326369, COSV71775928; called by muse, varscan2
